Somatic mutation profile of tumor specimen HCM-BROD-1128-C15-06A (aliquot HCM-BROD-1128-C15-06A-01D-A881-36) from HCMI case HCM-BROD-1128-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 56.3 years (20,546 days).
Specimen HCM-BROD-1128-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79ab7020-affd-4e4d-8577-415365dd931c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1128-C15-10A (Blood Derived Normal), aliquot HCM-BROD-1128-C15-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e01e77d-d240-43bd-8915-f0ad1dddbc2e

The open-access MAF lists 167 somatic variants for this specimen: 105 protein-altering or splice-affecting, 54 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 54, Intron 6, Nonsense Mutation 6, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 125/342 reads (37%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs928853508, COSV51561936; called by muse, mutect2, varscan2
- ADRA1B | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 33/577 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as rs1415252154; called by muse, mutect2
- AVIL | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 52/2221 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57684446; called by muse, mutect2
- BICRA | c.4211C>T p.T1404M | Missense Mutation (SNP) | VAF 330/1013 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1264919160; called by muse, mutect2, varscan2
- C8B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs756905287, COSV64779151; called by muse, mutect2, varscan2
- CNGB1 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs374172975; called by muse, mutect2, varscan2
- CNTNAP3 | c.2865G>T p.E955D | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1317961518; called by muse, mutect2
- CROCC | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 51/455 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs778887976; called by muse, mutect2, varscan2
- CTNNA1 | c.2375T>A p.I792N | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57079607; called by muse, varscan2
- DBNDD2 | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 42/736 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs928398906; called by muse, mutect2
- DKK1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 43/517 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs545596036; called by muse, mutect2
- DNAJB4 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs188409967; called by muse, mutect2, varscan2
- DSE | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs201564300; called by muse, mutect2, varscan2
- DZIP1 | c.2033C>T p.P678L (on ENST00000347108; = p.P659L on NM_014934.5) | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61266306; called by muse, mutect2
- EPS15L1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1272025635; called by muse, mutect2
- F9 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 53/235 reads (23%) | catalogued as CM094081, CM940708; called by muse, mutect2, varscan2
- FAM170B | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 101/392 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs775087170, COSV61253338; called by muse, varscan2
- FGFR2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 131/512 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs1041970177; called by muse, mutect2, varscan2
- FNDC3B | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV61040828; called by muse, mutect2
- GBX1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 81/740 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1240273534; called by muse, varscan2
- H2BC18 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.147); catalogued as COSV100516193; called by muse, mutect2, varscan2
- IPO8 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV99804659; called by muse, mutect2
- MAGEC1 | c.3325G>T p.D1109Y | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99596770; called by muse, mutect2, varscan2
- MYOM2 | c.1583T>A p.V528D | Missense Mutation (SNP) | VAF 105/482 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50734375; called by muse, mutect2, varscan2
- OR1F1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs546950482, COSV58961193; called by muse, mutect2, varscan2
- OSBP2 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs771660831; called by muse, mutect2
- PCLO | c.11817A>T p.Q3939H | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100428853, COSV61660580, COSV61676960; called by muse, mutect2
- PDE10A | c.2091G>T p.W697C | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63102324; called by muse, mutect2, varscan2
- PHF20L1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 40/457 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99620437; called by muse, mutect2
- PLEKHG2 | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 52/805 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1280005619; called by muse, mutect2
- PRRT1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 122/779 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52997791; called by muse, mutect2, varscan2
- RIMKLB | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55236342; called by muse, mutect2, varscan2
- RPS27A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99703108; called by muse, mutect2
- RPTN | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 54/554 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1167555229, COSV60167211; called by muse, mutect2
- SGK2 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 51/684 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as rs774838630, COSV58314725; called by muse, mutect2
- THRB | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 21/389 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1029651348, COSV99769564; called by muse, mutect2
- TP53BP1 | c.5420A>G p.D1807G | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1466930077; called by muse, mutect2, varscan2
- TPO | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 20/798 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61093582; called by muse, mutect2
- TREM2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs374248493; called by muse, mutect2, varscan2
- VSTM2B | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 52/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59260446; called by muse, mutect2, varscan2
- WDFY4 | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs952804690, COSV57430791; called by muse, mutect2, varscan2
- WRAP73 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 81/476 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs149451409; called by muse, mutect2, varscan2
- ZNF526 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as rs754975026; called by muse, mutect2, varscan2
- ABCC2 | c.3748C>G p.Q1250E | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- AC008397.2 | c.648C>G p.C216W | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ACTN4 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 110/1338 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- ADCY8 | c.2546T>A p.V849D | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ADGRV1 | c.4571C>T p.S1524L | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK9 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AKAP13 | c.7840G>A p.E2614K (on ENST00000394518 / NM_007200.5; = p.E2618K on NM_006738.6) | Missense Mutation (SNP) | VAF 17/505 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2
- AKNA | c.3433G>T p.G1145C | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- ANHX | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARMC3 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP13A4 | c.1911_1912dup p.T638Rfs*22 | Frame Shift Ins (INS) | VAF 27/205 reads (13%) | called by mutect2, pindel, varscan2
- ATP1A2 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 122/478 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP5F1C | c.798G>C p.E266D | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.3905A>T p.K1302M | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CAPN8 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- CBLB | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 27/313 reads (9%) | called by muse, mutect2
- CCDC83 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- CELF4 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL4A1 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.6037T>G p.F2013V | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA1 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CTSZ | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 121/440 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CYP2D7 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DIS3L2 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DLL3 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 526/1075 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DMXL2 | c.8887G>A p.E2963K | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOK5 | c.728A>C p.N243T | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); called by muse, mutect2
- DUS2 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EBF1 | c.1073_1074del p.R358Ifs*11 | Frame Shift Del (DEL) | VAF 26/243 reads (11%) | called by mutect2, pindel, varscan2
- EIF2S3B | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 158/592 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ESR1 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 110/540 reads (20%) | called by muse, mutect2, varscan2
- GAS2L1 | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GJD4 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 100/608 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- GLCCI1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GP6 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 60/521 reads (12%) | called by muse, mutect2, varscan2
- H3C10 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- HP | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPP5B | c.1861C>G p.H621D (on ENST00000373023; = p.H541D on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM6B | c.2410C>T p.L804F | Missense Mutation (SNP) | VAF 30/867 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.113); called by muse, mutect2
- LIPI | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- LMTK3 | c.768C>G p.H256Q | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM | c.3259A>C p.I1087L | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); called by muse, mutect2
- PHACTR3 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2
- PTPRZ1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- QSOX1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 66/616 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RAP1GDS1 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1CC1 | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RBMS2 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- RIMKLB | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 37/409 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2
- RNF4 | c.52A>T p.K18* | Nonsense Mutation (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- RRBP1 | c.2341C>T p.R781W (on ENST00000377813 / NM_001365613.2; = p.R348W on NM_004587.3) | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC1 | c.4062C>G p.F1354L | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNTG2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- TAAR6 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TBC1D19 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- TNN | c.1745A>G p.Q582R | Missense Mutation (SNP) | VAF 49/478 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- XKR6 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XRCC4 | c.462T>A p.D154E | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF33B | c.1411T>C p.C471R | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF763 | c.445C>G p.P149A (on ENST00000358987 / NM_001367172.2; = p.P152A on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ABCA2 | c.6873C>T p.N2291= (on ENST00000614293; = p.N2261= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/422 reads (15%) | catalogued as rs371356634; called by muse, varscan2
- AC127029.3 | c.837C>T p.Y279= | Silent (SNP) | VAF 114/507 reads (22%) | catalogued as rs753659458, COSV60111458; called by muse, mutect2, varscan2
- ACSF3 | c.1395G>A p.Q465= | Silent (SNP) | VAF 44/315 reads (14%) | catalogued as rs1451312853; called by muse, mutect2, varscan2
- AKNA | c.3432A>G p.R1144= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- ATG7 | c.108C>T p.N36= | Silent (SNP) | VAF 35/296 reads (12%) | catalogued as rs1029656328; called by muse, varscan2
- BCR | c.3630G>A p.T1210= | Silent (SNP) | VAF 68/420 reads (16%) | catalogued as rs531259855; called by muse, varscan2
- BNIP1 | c.30G>T p.R10= | Silent (SNP) | VAF 44/407 reads (11%) | catalogued as rs768368776; called by muse, mutect2, varscan2
- BRSK1 | c.1632C>T p.V544= | Silent (SNP) | VAF 87/642 reads (14%) | catalogued as rs1188306016; called by muse, mutect2, varscan2
- CBARP | c.900G>A p.P300= (on ENST00000382477; = p.P280= on NM_152769.3) | Silent (SNP) | VAF 36/729 reads (5%) | catalogued as rs938268200; called by muse, mutect2
- CCDC148 | c.1128C>T p.A376= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- CCNJL | c.36C>T p.A12= | Silent (SNP) | VAF 76/477 reads (16%) | catalogued as rs756623912; called by muse, mutect2, varscan2
- CLEC14A | c.687C>T p.D229= | Silent (SNP) | VAF 67/433 reads (15%) | catalogued as COSV60561971; called by muse, mutect2, varscan2
- CSNK1A1L | c.912A>G p.K304= | Silent (SNP) | VAF 98/408 reads (24%) | called by muse, mutect2, varscan2
- DAB1 | c.1101G>A p.P367= (on ENST00000371231; = p.P334= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 70/427 reads (16%) | catalogued as rs201974535, COSV64691430, COSV64694343; called by muse, mutect2, varscan2
- DCDC2C | c.267C>T p.R89= | Silent (SNP) | VAF 52/462 reads (11%) | catalogued as rs1157942453; called by muse, mutect2, varscan2
- DCHS2 | c.261C>T p.R87= | Silent (SNP) | VAF 225/594 reads (38%) | catalogued as COSV100251985; called by muse, mutect2, varscan2
- FAT1 | c.1257C>A p.L419= | Silent (SNP) | VAF 19/292 reads (7%) | catalogued as COSV71671618; called by muse, mutect2
- FNDC11 | c.309C>T p.I103= | Silent (SNP) | VAF 56/844 reads (7%) | catalogued as rs200404643; called by muse, mutect2
- GRAMD2B | c.741C>T p.F247= | Silent (SNP) | VAF 46/228 reads (20%) | called by muse, mutect2, varscan2
- HJV | c.303C>T p.L101= | Silent (SNP) | VAF 76/893 reads (9%) | called by muse, mutect2
- HMCN1 | c.12489C>A p.L4163= | Silent (SNP) | VAF 24/293 reads (8%) | called by muse, mutect2
- HOXD9 | c.132C>T p.G44= | Silent (SNP) | VAF 69/653 reads (11%) | catalogued as rs1426870162, COSV50890666; called by muse, mutect2, varscan2
- HS3ST5 | c.468C>T p.S156= | Silent (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- IFNW1 | c.450C>A p.I150= | Silent (SNP) | VAF 34/251 reads (14%) | called by muse, mutect2, varscan2
- IGHV3-13 | c.288C>T p.S96= | Silent (SNP) | VAF 30/231 reads (13%) | catalogued as rs1555437082; called by muse, mutect2, varscan2
- JAKMIP1 | c.1353A>G p.S451= | Silent (SNP) | VAF 48/359 reads (13%) | called by muse, mutect2, varscan2
- KCNG1 | c.1029C>T p.R343= | Silent (SNP) | VAF 73/713 reads (10%) | catalogued as rs772473814, COSV65370332; called by muse, mutect2, varscan2
- LRRC38 | c.30C>T p.A10= | Silent (SNP) | VAF 30/375 reads (8%) | called by muse, mutect2
- MAML3 | c.2202C>T p.P734= | Silent (SNP) | VAF 19/530 reads (4%) | called by muse, mutect2
- MARK4 | c.1107G>A p.R369= | Silent (SNP) | VAF 22/520 reads (4%) | called by muse, mutect2
- MRPL2 | c.885C>T p.Y295= | Silent (SNP) | VAF 55/397 reads (14%) | catalogued as rs1299707479; called by muse, mutect2, varscan2
- MYH4 | c.3682C>T p.L1228= | Silent (SNP) | VAF 41/344 reads (12%) | catalogued as COSV99701674; called by mutect2, varscan2
- NBAS | c.297G>A p.K99= | Silent (SNP) | VAF 22/289 reads (8%) | catalogued as rs773207325; called by muse, mutect2
- NDUFS6 | c.258G>A p.A86= | Silent (SNP) | VAF 77/618 reads (12%) | catalogued as rs758741439; called by muse, mutect2, varscan2
- NKPD1 | c.1381C>T p.L461= | Silent (SNP) | VAF 136/1031 reads (13%) | called by muse, mutect2, varscan2
- NOL4L | c.225G>A p.K75= | Silent (SNP) | VAF 179/895 reads (20%) | called by muse, mutect2, varscan2
- OLIG1 | c.741C>T p.C247= | Silent (SNP) | VAF 87/367 reads (24%) | called by muse, mutect2, varscan2
- OR2V2 | c.366C>T p.D122= | Silent (SNP) | VAF 47/382 reads (12%) | catalogued as rs1218364415; called by muse, mutect2, varscan2
- OR9H1P | c.720T>A p.A240= | Silent (SNP) | VAF 81/346 reads (23%) | called by muse, mutect2, varscan2
- PKD2 | c.2586C>T p.A862= | Silent (SNP) | VAF 34/319 reads (11%) | catalogued as rs373043298; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1 | c.3453G>A p.P1151= | Silent (SNP) | VAF 34/447 reads (8%) | catalogued as COSV61878001; called by muse, mutect2
- PNCK | c.567C>T p.Y189= (on ENST00000340888 / NM_001366975.1; = p.Y272= on NM_001039582.3) | Silent (SNP) | VAF 144/361 reads (40%) | catalogued as rs377279617, COSV100562314; called by muse, mutect2, varscan2
- POLRMT | c.2412C>T p.G804= | Silent (SNP) | VAF 36/645 reads (6%) | called by muse, mutect2
- PPP2R2C | c.849C>T p.S283= | Silent (SNP) | VAF 45/350 reads (13%) | catalogued as rs771757681, COSV59446130; called by muse, mutect2, varscan2
- PTN | c.75A>T p.A25= | Silent (SNP) | VAF 95/284 reads (33%) | called by muse, mutect2, varscan2
- PTPN5 | c.570C>A p.S190= | Silent (SNP) | VAF 47/385 reads (12%) | called by muse, mutect2, varscan2
- RASGRP1 | c.756C>T p.N252= | Silent (SNP) | VAF 60/372 reads (16%) | catalogued as rs36111378, COSV60363503; called by muse, mutect2, varscan2
- SALL3 | c.1767C>T p.G589= | Silent (SNP) | VAF 109/810 reads (13%) | catalogued as rs745938058; called by muse, mutect2, varscan2
- SETDB1 | c.1563G>T p.G521= | Silent (SNP) | VAF 95/303 reads (31%) | called by muse, mutect2, varscan2
- SF3B1 | c.2016T>C p.A672= | Silent (SNP) | VAF 68/311 reads (22%) | called by muse, mutect2, varscan2
- SHANK2 | c.90A>G p.E30= | Silent (SNP) | VAF 58/1696 reads (3%) | called by muse, mutect2
- SOGA3 | c.486G>A p.P162= | Silent (SNP) | VAF 77/530 reads (15%) | catalogued as rs932561812; called by muse, mutect2, varscan2
- TMEM271 | c.150C>T p.G50= | Silent (SNP) | VAF 74/664 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.312C>A p.T104= | Silent (SNP) | VAF 58/203 reads (29%) | called by muse, mutect2, varscan2
- ABHD17A | c.332+315G>A | Intron (SNP) | VAF 65/375 reads (17%) | called by muse, mutect2, varscan2
- CCL7 | c.77-10T>C | Intron (SNP) | VAF 60/477 reads (13%) | called by muse, mutect2, varscan2
- DLG1 | c.483+10632G>A | Intron (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1469C>T | 3'UTR (SNP) | VAF 59/582 reads (10%) | catalogued as rs369758941; ClinVar: uncertain significance; called by muse, mutect2
- KCNMA1 | c.378+268C>T | Intron (SNP) | VAF 49/508 reads (10%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-15279G>A | Intron (SNP) | VAF 35/273 reads (13%) | catalogued as rs1383065992; called by muse, mutect2, varscan2
- MMD2 | c.*910C>A | 3'UTR (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2
- TTN | c.10360+3944A>C | Intron (SNP) | VAF 56/229 reads (24%) | called by muse, mutect2, varscan2
